Somatic mutation profile of tumor specimen HTMCP-03-06-02129-01A (aliquot HTMCP-03-06-02129-01A-01D-5099) from CGCI case HTMCP-03-06-02129, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02129-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78e2191f-479d-4c99-ab8c-d7a9215edcaa.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02129-10A (Blood Derived Normal), aliquot HTMCP-03-06-02129-10A-01D-5099; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cda9562-4a33-47c0-abd1-8db3c61c816b

The open-access MAF lists 166 somatic variants for this specimen: 104 protein-altering or splice-affecting, 45 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 45, Intron 12, Nonsense Mutation 10, 5'Flank 2, Splice Site 2, 3'UTR 2, In Frame Del 1, RNA 1, Splice Region 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>A p.S310Y | Missense Mutation (SNP) | VAF 49/92 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.697C>G p.L233V | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55748124; called by muse, mutect2, varscan2
- AR | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057521121, CM102200; called by muse, mutect2, varscan2
- ARHGAP35 | c.3949G>A p.V1317M | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV68330140, COSV68330679; called by muse, mutect2, varscan2
- ARMCX2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as rs782242885, COSV57530775; called by muse, mutect2, varscan2
- ATAD5 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.413); catalogued as rs772072992; called by muse, mutect2, varscan2
- ATP10B | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV59143159; called by muse, mutect2, varscan2
- BICRA | c.3658C>T p.R1220W | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs765432251, COSV67606172; called by muse, mutect2, varscan2
- CAMTA1 | c.3143G>A p.R1048Q | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.984); catalogued as rs747988937; called by muse, mutect2, varscan2
- CASP8 | c.698G>A p.R233Q (on ENST00000432109 / NM_033355.3; = p.R250Q on NM_001228.4) | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as rs771150445, COSV51844924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC141 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV55369334; called by muse, mutect2, varscan2
- CDH11 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.45); PolyPhen probably damaging (1); catalogued as COSV51773053, COSV51774266; called by muse, mutect2, varscan2
- CRACD | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746752030, COSV51716359; called by muse, mutect2, varscan2
- CUX1 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52909751; called by muse, mutect2, varscan2
- DHX34 | c.1392G>A p.M464I | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs1437710499; called by muse, mutect2, varscan2
- DNAH17 | c.9599C>T p.S3200F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs751225361, COSV67759255; called by muse, mutect2, varscan2
- DSP | c.2631-1G>C p.X877_splice | Splice Site (SNP) | VAF 53/130 reads (41%) | catalogued as COSV65794773; called by muse, mutect2, varscan2
- DYSF | c.5119C>G p.Q1707E | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs199827126; called by muse, mutect2, varscan2
- F9 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 89/269 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs766259893, COSV99496956; called by muse, mutect2, varscan2
- FLNC | c.7435G>A p.D2479N | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.643); catalogued as rs1173970601, COSV57951661; called by muse, mutect2, varscan2
- FSD2 | c.16G>T p.G6W | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV58011529; called by muse, mutect2
- GEMIN4 | c.1159del p.L387* | Frame Shift Del (DEL) | VAF 32/87 reads (37%) | catalogued as rs1170267239; called by mutect2, pindel, varscan2
- H2BC8 | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.32); catalogued as rs1448644205, COSV99773215; called by muse, mutect2, varscan2
- HGF | c.625+1G>A p.X209_splice | Splice Site (SNP) | VAF 33/122 reads (27%) | catalogued as COSV55957827; called by muse, mutect2, varscan2
- IGF2R | c.6784G>A p.E2262K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1200823607; called by muse, mutect2, varscan2
- JARID2 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 82/230 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as rs376870539; called by muse, mutect2, varscan2
- KIAA1841 | c.1636C>G p.L546V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.914); catalogued as COSV54379092; called by muse, mutect2, varscan2
- L3MBTL3 | c.363G>C p.E121D | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV100695695; called by muse, mutect2, varscan2
- MAP3K1 | c.4073C>T p.S1358L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV101267095; called by muse, mutect2, varscan2
- MED12 | c.1861C>T p.R621* | Nonsense Mutation (SNP) | VAF 28/178 reads (16%) | catalogued as COSV61333117; called by muse, mutect2, varscan2
- MEGF8 | c.3712G>A p.E1238K (on ENST00000251268 / NM_001271938.2; = p.E1171K on NM_001410.3) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as rs377750684; called by muse, varscan2
- MTCL1 | c.1876G>A p.D626N (on ENST00000306329 / NM_001378206.1; = p.D266N on NM_015210.4) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs909200057, COSV60407223, COSV60410559; called by muse, mutect2, varscan2
- MYO5A | c.2017G>C p.D673H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV62562580; called by muse, mutect2, varscan2
- NKAP | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV65056547; called by muse, mutect2, varscan2
- NR3C1 | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 33/108 reads (31%) | catalogued as rs895053872; called by muse, mutect2, varscan2
- PCDHA4 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.315); catalogued as rs782467255; called by muse, mutect2, varscan2
- PCNT | c.6743C>T p.S2248L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs200670600; called by muse, mutect2, varscan2
- PKN2 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764555959; called by muse, mutect2, varscan2
- PLEKHG3 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs770616036; called by muse, varscan2
- RYR1 | c.4259G>A p.R1420H | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs150499158; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SETX | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as CM050776; called by muse, varscan2
- SPEF2 | c.2893G>T p.E965* | Nonsense Mutation (SNP) | VAF 12/172 reads (7%) | catalogued as COSV61544106; called by muse, mutect2
- SUSD2 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1003803304; called by muse, mutect2, varscan2
- TRIP6 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs746042132, COSV99307762; called by muse, mutect2, varscan2
- ZMAT1 | c.1848G>C p.E616D | Missense Mutation (SNP) | VAF 65/339 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.073); catalogued as COSV100858760; called by muse, mutect2, varscan2
- AHDC1 | c.3775G>A p.G1259S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.06); called by muse, mutect2
- AK7 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- ARMC9 | c.1672G>C p.E558Q | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- CACHD1 | c.1209G>C p.Q403H | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CAMSAP2 | c.3827C>T p.S1276F (on ENST00000236925 / NM_001297707.2; = p.S1265F on NM_203459.3) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- CAMSAP2 | c.4019C>A p.S1340* (on ENST00000236925 / NM_001297707.2; = p.S1329* on NM_203459.3) | Nonsense Mutation (SNP) | VAF 26/87 reads (30%) | called by muse, mutect2, varscan2
- CHD2 | c.60G>C p.S20= | Splice Region (SNP) | VAF 24/136 reads (18%) | called by muse, varscan2
- CLK1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 94/276 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL27A1 | c.5221G>C p.E1741Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- DDX27 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2
- DDX27 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DNAH6 | c.6409G>C p.E2137Q | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- DNAJC14 | c.139C>G p.P47A | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); called by muse, varscan2
- DNAJC14 | c.110C>G p.S37* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | called by muse, varscan2
- DYNC1H1 | c.6541G>A p.E2181K | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EGFLAM | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- FAM161B | c.2123C>T p.S708L (on ENST00000651776; = p.S645L on NM_152445.3) | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.105); called by muse, mutect2
- GRIN2A | c.425C>A p.S142Y | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- H1-5 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC1 | c.7864G>T p.E2622* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- HMCN1 | c.16147C>T p.Q5383* | Nonsense Mutation (SNP) | VAF 35/162 reads (22%) | called by muse, mutect2, varscan2
- HS6ST2 | c.1720A>G p.N574D | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HUWE1 | c.10829G>A p.R3610Q | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- IDH3B | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- IFT122 | c.3482C>G p.S1161* (on ENST00000348417 / NM_052989.3; = p.S1102* on NM_018262.4) | Nonsense Mutation (SNP) | VAF 10/12 reads (83%) | called by muse, mutect2, varscan2
- MAP4K1 | c.2068A>G p.T690A | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- MDGA2 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.041); called by muse, mutect2
- MRTFA | c.785C>G p.S262C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MYO18B | c.7169C>T p.S2390F | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MYOM3 | c.2923G>A p.D975N | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- NCKAP5L | c.2614C>T p.Q872* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- NES | c.1768G>C p.E590Q | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- NONO | c.1372G>T p.A458S | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NPHP4 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NSMAF | c.1061G>C p.G354A | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCNX1 | c.5054C>T p.S1685F | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLXNA2 | c.4252G>C p.E1418Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- PLXNB1 | c.4087G>C p.D1363H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ROCK2 | c.3028_3030del p.E1010del | In Frame Del (DEL) | VAF 20/105 reads (19%) | called by pindel, varscan2
- RP1 | c.1471A>G p.S491G | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRGAP1 | c.1762G>T p.E588* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- STAB2 | c.3909G>C p.E1303D | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- TAF1 | c.151dup p.A51Gfs*10 | Frame Shift Ins (INS) | VAF 17/125 reads (14%) | called by mutect2, pindel, varscan2
- TCP11L2 | c.1379C>A p.P460H | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TJP1 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM39B | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TNRC6A | c.797G>A p.R266K | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC16 | c.2244G>C p.E748D | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TTC6 | c.213G>C p.K71N (on ENST00000267368; = p.K1340N on NM_001310135.3) | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TTF2 | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TTF2 | c.2692G>C p.E898Q | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- USP29 | c.322C>G p.Q108E | Missense Mutation (SNP) | VAF 70/440 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- VPS8 | c.2867C>G p.S956C (on ENST00000625842 / NM_001349294.1; = p.S954C on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- WDR90 | c.2757C>G p.I919M | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- WWC3 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- XRCC5 | c.217C>G p.Q73E | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ZNF469 | c.3586G>A p.E1196K (on ENST00000437464; = p.E1224K on NM_001367624.2) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ZNF594 | c.1559A>G p.E520G | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF687 | c.1308G>T p.M436I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AATK | c.948G>A p.K316= (on ENST00000326724 / NM_001080395.3; = p.K213= on NM_004920.2) | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs544809507; called by muse, mutect2, varscan2
- AFF2 | c.432G>A p.L144= | Silent (SNP) | VAF 41/241 reads (17%) | catalogued as rs782237480, COSV60669237; called by muse, mutect2, varscan2
- APOB | c.2019G>A p.L673= | Silent (SNP) | VAF 20/149 reads (13%) | called by muse, mutect2, varscan2
- CADM1 | c.492C>T p.V164= | Silent (SNP) | VAF 44/162 reads (27%) | called by muse, mutect2, varscan2
- CAMSAP3 | c.1281C>T p.L427= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs903418550; called by muse, mutect2, varscan2
- CFAP54 | c.8049C>T p.L2683= | Silent (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
- CIITA | c.2358G>A p.Q786= | Silent (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- CTNND2 | c.2436G>A p.K812= | Silent (SNP) | VAF 29/342 reads (8%) | catalogued as COSV58883365; called by muse, mutect2
- DNAJC14 | c.561C>T p.S187= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as rs748085515; called by muse, mutect2, varscan2
- DOT1L | c.507C>G p.V169= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs760870688; called by muse, varscan2
- DSP | c.2139G>A p.Q713= | Silent (SNP) | VAF 56/158 reads (35%) | called by muse, varscan2
- EXPH5 | c.3669G>A p.G1223= | Silent (SNP) | VAF 52/168 reads (31%) | called by muse, mutect2, varscan2
- FANCA | c.690C>T p.V230= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs942275917, COSV66882699; called by muse, mutect2, varscan2
- FGD3 | c.423G>A p.Q141= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs991883084; called by muse, mutect2, varscan2
- FOXL1 | c.96C>T p.F32= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV57214395; called by muse, mutect2, varscan2
- FRMPD4 | c.756G>A p.R252= | Silent (SNP) | VAF 36/101 reads (36%) | called by muse, mutect2, varscan2
- HECTD1 | c.2091C>T p.I697= | Silent (SNP) | VAF 44/279 reads (16%) | catalogued as COSV67949073; called by muse, mutect2, varscan2
- HMCN2 | c.582C>T p.F194= | Silent (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- HR | c.1632C>T p.S544= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs148562279; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL16 | c.1869C>T p.C623= | Silent (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- ITGAL | c.3165C>G p.L1055= | Silent (SNP) | VAF 21/118 reads (18%) | called by muse, mutect2, varscan2
- ITPR2 | c.4221G>A p.V1407= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as COSV67269337; called by muse, mutect2, varscan2
- KIAA1549 | c.4011C>A p.A1337= | Silent (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- MAP3K19 | c.3354G>T p.L1118= | Silent (SNP) | VAF 59/178 reads (33%) | called by muse, mutect2, varscan2
- MAPRE3 | c.90C>G p.L30= | Silent (SNP) | VAF 31/158 reads (20%) | called by muse, mutect2, varscan2
- MAST3 | c.1005G>T p.L335= | Silent (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- MYH7 | c.252C>T p.F84= | Silent (SNP) | VAF 68/101 reads (67%) | catalogued as rs267603955, COSV62515908; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOL8 | c.1495C>T p.L499= | Silent (SNP) | VAF 55/190 reads (29%) | catalogued as rs1272074015; called by muse, mutect2, varscan2
- PCDHA12 | c.270C>T p.I90= | Silent (SNP) | VAF 68/240 reads (28%) | catalogued as rs782079077, COSV100252533, COSV56480091; called by muse, mutect2, varscan2
- PCDHA5 | c.1362C>T p.F454= | Silent (SNP) | VAF 44/143 reads (31%) | catalogued as rs536422534, COSV100972196; called by muse, mutect2, varscan2
- PKHD1 | c.1446G>A p.V482= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs745870261; called by muse, mutect2, varscan2
- PLD1 | c.1686C>G p.L562= | Silent (SNP) | VAF 15/174 reads (9%) | called by muse, mutect2
- PLEC | c.8592C>T p.L2864= (on ENST00000322810 / NM_201380.4; = p.L2754= on NM_000445.5) | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV59702804; called by muse, mutect2, varscan2
- POLQ | c.3135A>G p.R1045= | Silent (SNP) | VAF 38/144 reads (26%) | called by muse, mutect2, varscan2
- RPS6KB2 | c.900C>T p.V300= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs753326716; called by muse, mutect2, varscan2
- RYR2 | c.9642C>G p.L3214= | Silent (SNP) | VAF 23/118 reads (19%) | called by muse, mutect2, varscan2
- STAG1 | c.2163G>A p.K721= | Silent (SNP) | VAF 23/91 reads (25%) | called by muse, mutect2, varscan2
- SYTL2 | c.2076G>A p.L692= (on ENST00000528231 / NM_001162951.2; = p.L668= on NM_032943.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/99 reads (30%) | called by muse, mutect2, varscan2
- SZT2 | c.4251G>A p.L1417= (on ENST00000634258 / NM_001365999.1; = p.L1360= on NM_015284.4) | Silent (SNP) | VAF 31/86 reads (36%) | called by muse, mutect2, varscan2
- TRIM64B | c.945C>T p.L315= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs1242942094; called by mutect2, varscan2
- TRIO | c.834G>A p.E278= | Silent (SNP) | VAF 20/336 reads (6%) | called by muse, mutect2
- USP49 | c.1092C>T p.L364= | Silent (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
- VWA3B | c.1077C>G p.A359= | Silent (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- ZNF473 | c.2208G>A p.G736= | Silent (SNP) | VAF 29/142 reads (20%) | called by muse, mutect2, varscan2
- ZNF473 | c.2433G>A p.E811= | Silent (SNP) | VAF 30/189 reads (16%) | called by muse, mutect2, varscan2
- AC025884.2 | n.591C>T | RNA (SNP) | VAF 20/262 reads (8%) | catalogued as rs1354637687; called by muse, mutect2
- AC091951.3 | n.446+3428G>C | Intron (SNP) | VAF 16/395 reads (4%) | called by muse, mutect2
- AC107023.1 | n.26-7129G>A | Intron (SNP) | VAF 36/153 reads (24%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840745 G>C | 5'Flank (SNP) | VAF 11/98 reads (11%) | called by mutect2, varscan2
- ATP2B3 | c.3342+4624C>G | Intron (SNP) | VAF 41/166 reads (25%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+1939G>A | Intron (SNP) | VAF 81/386 reads (21%) | called by muse, mutect2, varscan2
- CFP | c.228-208G>C | Intron (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- CREBZF | c.*233C>T | 3'UTR (SNP) | VAF 45/117 reads (38%) | called by muse, mutect2, varscan2
- DNAH14 | c.2938+1953G>C | Intron (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- DNM2 | c.1336-1087G>A | Intron (SNP) | VAF 17/35 reads (49%) | catalogued as COSV100116713; called by muse, mutect2, varscan2
- FAM131A | chr3:184338447 C>T | 5'Flank (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- HSPG2 | c.7873+41G>C | Intron (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- PDZD7 | c.367+21G>A | Intron (SNP) | VAF 15/57 reads (26%) | catalogued as COSV64646229; called by muse, mutect2, varscan2
- PNMA5 | c.*6G>A | 3'UTR (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- PTPRK | c.495+61A>T | Intron (SNP) | VAF 35/136 reads (26%) | catalogued as rs1415048380; called by muse, mutect2, varscan2
- TTN | c.10360+4063G>T | Intron (SNP) | VAF 41/129 reads (32%) | called by muse, mutect2, varscan2
- ZNF219 | c.-83-728G>A | Intron (SNP) | VAF 46/84 reads (55%) | called by muse, varscan2
